Somatic mutation profile of tumor specimen C3L-09082-05 (aliquot CPT0482390006) from CPTAC case C3L-09082, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 68.4 years (24,977 days).
Specimen C3L-09082-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf503fdb-fb96-4a1c-9a3d-79167309b07d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09082-31 (Blood Derived Normal), aliquot CPT0482500003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eeed2ac-6593-4e57-add6-47c3c357eaed

The open-access MAF lists 121 somatic variants for this specimen: 82 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 36, Nonsense Mutation 8, Intron 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INA | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.061); catalogued as rs920363358, CM1512510; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 70/223 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by mutect2, varscan2
- ABCA13 | c.14956A>T p.N4986Y | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68945250; called by mutect2, varscan2
- ABCG5 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs376129056, COSV53209176; ClinVar: uncertain significance; called by mutect2, varscan2
- ABLIM3 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs747716272, COSV58641823; called by mutect2, varscan2
- ATXN7L1 | c.1224A>G p.I408M | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.564); catalogued as rs139507361; called by mutect2, varscan2
- CDX4 | c.20T>A p.L7* | Nonsense Mutation (SNP) | VAF 82/179 reads (46%) | catalogued as COSV100999119; called by mutect2, varscan2
- CSMD3 | c.10186G>T p.D3396Y (on ENST00000297405 / NM_001363185.1; = p.D3227Y on NM_052900.3) | Missense Mutation (SNP) | VAF 49/425 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52116914; called by mutect2, varscan2
- CSNKA2IP | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV101359565; called by mutect2, varscan2
- DKK3 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs770444984, COSV58869480; called by mutect2, varscan2
- DPP10 | c.2329T>G p.F777V | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59710632, COSV59721562; called by mutect2, varscan2
- EPHA10 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs202036880; called by mutect2, varscan2
- ERICH3 | c.2737T>A p.L913M | Missense Mutation (SNP) | VAF 165/437 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as COSV100446188, COSV58610781; called by mutect2, varscan2
- EXOC3L2 | c.1503G>T p.E501D | Missense Mutation (SNP) | VAF 186/440 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.279); catalogued as COSV52972532, COSV52972902; called by mutect2, varscan2
- GALNTL6 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101487914; called by mutect2, varscan2
- HECW1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 55/411 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.439); catalogued as rs1313411241, COSV67831345; called by mutect2, varscan2
- HOXB9 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 96/486 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757942055; called by mutect2, varscan2
- IGKV3-15 | c.157T>G p.L53V | Missense Mutation (SNP) | VAF 60/490 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs768194531; called by mutect2, varscan2
- KIF25 | c.1093C>T p.R365* (on ENST00000354419 / NM_030615.2; = p.R313* on NM_005355.3) | Nonsense Mutation (SNP) | VAF 176/541 reads (33%) | catalogued as rs756272849, COSV63026752; called by mutect2, varscan2
- KRT75 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 112/322 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs551243973; called by mutect2, varscan2
- NLGN1 | c.384A>C p.E128D | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64338625; called by mutect2, varscan2
- PHF2 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs758091302; called by mutect2, varscan2
- REL | c.861C>G p.Y287* | Nonsense Mutation (SNP) | VAF 41/223 reads (18%) | catalogued as COSV99692343, COSV99692497; called by mutect2, varscan2
- SDK1 | c.3694C>T p.R1232W | Missense Mutation (SNP) | VAF 85/465 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765423627, COSV67362071, COSV67387428; called by mutect2, varscan2
- SIGLEC1 | c.4468G>A p.A1490T | Missense Mutation (SNP) | VAF 166/701 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs138521367; called by mutect2, varscan2
- SLC6A8 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM109753; called by mutect2, varscan2
- STON1 | c.1508A>C p.K503T | Missense Mutation (SNP) | VAF 83/364 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV59129174; called by mutect2, varscan2
- SYNE1 | c.14500C>T p.R4834* (on ENST00000367255 / NM_182961.4; = p.R4763* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 43/418 reads (10%) | catalogued as rs766129413, COSV55042757; called by mutect2, varscan2
- SYTL5 | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs750671871, COSV52899155, COSV52901430, COSV52902505; called by mutect2, varscan2
- TMEM179 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs375505023; called by mutect2, varscan2
- TMTC1 | c.1627C>A p.L543I (on ENST00000539277 / NM_001193451.2; = p.L435I on NM_175861.3) | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as COSV99758336; called by mutect2, varscan2
- TNRC6C | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV56947560; called by mutect2, varscan2
- TRO | c.1865A>C p.K622T | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51499868; called by mutect2, varscan2
- TTN | c.54338A>C p.K18113T (on ENST00000591111; = p.K10689T on NM_003319.4) | Missense Mutation (SNP) | VAF 68/352 reads (19%) | PolyPhen possibly damaging (0.6); catalogued as COSV100596298, COSV59923859; called by mutect2, varscan2
- UTP25 | c.2201G>C p.G734A | Missense Mutation (SNP) | VAF 78/383 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101530937, COSV101530985; called by mutect2, varscan2
- ZFPM2 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 84/474 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1212226889, COSV65874699; called by mutect2, varscan2
- ZNF804B | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV100305295; called by mutect2, varscan2
- ADAM10 | c.56-3_57dup p.Q20* | Nonsense Mutation (INS) | VAF 16/102 reads (16%) | called by pindel, varscan2
- ADAMTS16 | c.3120A>C p.E1040D | Missense Mutation (SNP) | VAF 95/416 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by mutect2, varscan2
- ARHGAP31 | c.3325T>G p.L1109V | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ARMCX5-GPRASP2 | c.1295T>G p.L432R | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- ATXN2L | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- BSN | c.3630_3641del p.H1212_P1215del | In Frame Del (DEL) | VAF 66/380 reads (17%) | called by mutect2, pindel, varscan2
- CEBPZ | c.1808G>T p.C603F | Missense Mutation (SNP) | VAF 88/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CHST3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 116/406 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- COL14A1 | c.3809T>A p.V1270D | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by mutect2, varscan2
- CTSS | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CYP1B1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 70/391 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by mutect2, varscan2
- DARS2 | c.1112G>A p.C371Y | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.802); called by mutect2, varscan2
- DCAF8L1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 74/176 reads (42%) | called by mutect2, varscan2
- DCLK1 | c.994A>G p.S332G | Missense Mutation (SNP) | VAF 130/486 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.49); called by mutect2, varscan2
- DNAH14 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 64/322 reads (20%) | called by mutect2, varscan2
- DOCK6 | c.2129A>T p.E710V | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.826); called by mutect2, varscan2
- DYNC2H1 | c.8852C>T p.T2951I | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.285); called by mutect2, varscan2
- ERF | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 304/584 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by mutect2, varscan2
- FGF10 | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.059); called by mutect2, varscan2
- GABRB2 | c.313T>G p.L105V | Missense Mutation (SNP) | VAF 60/351 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- GPC5 | c.961T>G p.L321V | Missense Mutation (SNP) | VAF 60/447 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.021); called by mutect2, varscan2
- HAS1 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 52/512 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by mutect2, varscan2
- LY6G6F-LY6G6D | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 296/792 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- MUC16 | c.18382A>C p.T6128P | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by mutect2, varscan2
- MYLK | c.1312T>C p.S438P | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- NEO1 | c.1548A>C p.Q516H | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by mutect2, varscan2
- NSL1 | c.375del p.K125Nfs*17 | Frame Shift Del (DEL) | VAF 53/280 reads (19%) | called by mutect2, pindel, varscan2
- NWD2 | c.2783T>G p.L928R | Missense Mutation (SNP) | VAF 84/346 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by mutect2, varscan2
- PCDH19 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 126/274 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.513); called by mutect2, varscan2
- PCYT1A | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 74/354 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); called by mutect2, varscan2
- PLXNA4 | c.3803A>G p.D1268G | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- PPFIA4 | c.3090A>C p.L1030F (on ENST00000447715; = p.L1031F on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by mutect2, varscan2
- PPP2R2B | c.1133C>T p.S378L (on ENST00000394409; = p.S444L on NM_181674.2) | Missense Mutation (SNP) | VAF 120/309 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by mutect2, varscan2
- PRDM14 | c.1700T>G p.F567C | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by mutect2, varscan2
- RAI1 | c.5352C>A p.Y1784* | Nonsense Mutation (SNP) | VAF 120/362 reads (33%) | called by mutect2, varscan2
- SERTM1 | c.37A>C p.S13R | Missense Mutation (SNP) | VAF 149/518 reads (29%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by mutect2, varscan2
- SFMBT2 | c.1715T>G p.I572S | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by mutect2, varscan2
- SP5 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 42/400 reads (11%) | called by mutect2, varscan2
- SPATA48 | c.657A>C p.E219D | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- SREBF2 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 186/448 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0.01); called by mutect2, varscan2
- STARD13 | c.1317_1335del p.G440Sfs*54 (on ENST00000336934 / NM_001243476.3; = p.G322Sfs*54 on NM_052851.3) | Frame Shift Del (DEL) | VAF 152/535 reads (28%) | called by mutect2, pindel, varscan2
- TRMT10C | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TTN | c.9679A>G p.S3227G (on ENST00000591111; = p.S3181G on NM_003319.4) | Missense Mutation (SNP) | VAF 46/272 reads (17%) | PolyPhen probably damaging (0.987); called by mutect2, varscan2
- WDFY4 | c.5268A>C p.E1756D | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); called by mutect2, varscan2
- ZNF880 | c.1660G>A p.G554S | Missense Mutation (SNP) | VAF 56/466 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- BLZF1 | c.495G>A p.L165= | Silent (SNP) | VAF 52/220 reads (24%) | called by mutect2, varscan2
- CDAN1 | c.2245C>T p.L749= | Silent (SNP) | VAF 82/272 reads (30%) | called by mutect2, varscan2
- CNTN6 | c.2022T>G p.R674= | Silent (SNP) | VAF 64/334 reads (19%) | catalogued as COSV63171736; called by mutect2, varscan2
- CRTC1 | c.1422G>T p.P474= | Silent (SNP) | VAF 60/253 reads (24%) | catalogued as rs755612353; called by mutect2, varscan2
- CRYBB1 | c.384G>C p.S128= | Silent (SNP) | VAF 148/372 reads (40%) | called by mutect2, varscan2
- CSMD3 | c.10185T>A p.P3395= (on ENST00000297405 / NM_001363185.1; = p.P3226= on NM_052900.3) | Silent (SNP) | VAF 49/426 reads (12%) | called by mutect2, varscan2
- CUBN | c.2556A>G p.Q852= | Silent (SNP) | VAF 44/378 reads (12%) | catalogued as COSV64710110, COSV64721355, COSV64726238; called by mutect2, varscan2
- DCAF12L1 | c.390C>T p.I130= | Silent (SNP) | VAF 92/240 reads (38%) | catalogued as rs1056266108; called by mutect2, varscan2
- DNAH10 | c.12726G>A p.L4242= (on ENST00000409039; = p.L4181= on NM_207437.3) | Silent (SNP) | VAF 159/372 reads (43%) | catalogued as COSV53021533; called by mutect2, varscan2
- DOLK | c.1104G>A p.A368= | Silent (SNP) | VAF 50/397 reads (13%) | catalogued as rs765151256, COSV58281353; called by mutect2, varscan2
- ERCC2 | c.1065C>T p.P355= | Silent (SNP) | VAF 60/510 reads (12%) | called by mutect2, varscan2
- FLT3 | c.1614C>T p.I538= | Silent (SNP) | VAF 88/269 reads (33%) | catalogued as COSV54044366; called by mutect2, varscan2
- FOXG1 | c.972T>G p.T324= | Silent (SNP) | VAF 124/366 reads (34%) | called by mutect2, varscan2
- GATA4 | c.1308C>T p.H436= | Silent (SNP) | VAF 68/234 reads (29%) | catalogued as rs779684582; ClinVar: likely benign; called by mutect2, varscan2
- HIPK3 | c.1278T>C p.G426= | Silent (SNP) | VAF 32/256 reads (13%) | catalogued as COSV57562633; called by mutect2, varscan2
- HRH3 | c.951G>A p.P317= | Silent (SNP) | VAF 136/625 reads (22%) | catalogued as rs1188017651, COSV58050989; called by mutect2, varscan2
- IGKV3-11 | c.303A>G p.E101= | Silent (SNP) | VAF 58/374 reads (16%) | catalogued as rs377552459; called by mutect2, varscan2
- JRK | c.1485C>T p.D495= | Silent (SNP) | VAF 86/540 reads (16%) | catalogued as rs370638998; called by mutect2, varscan2
- KCNT1 | c.1497G>A p.A499= (on ENST00000488444; = p.A518= on NM_020822.3) | Silent (SNP) | VAF 77/289 reads (27%) | catalogued as rs756721305; ClinVar: likely benign; called by mutect2, varscan2
- KRT16 | c.654C>T p.A218= | Silent (SNP) | VAF 68/320 reads (21%) | catalogued as rs774364736; called by mutect2, varscan2
- KRTAP1-1 | c.408G>A p.V136= | Silent (SNP) | VAF 62/594 reads (10%) | catalogued as COSV100092123; called by mutect2, varscan2
- LRRN4 | c.339G>A p.A113= | Silent (SNP) | VAF 162/698 reads (23%) | catalogued as rs1454031525, COSV66646315; called by mutect2, varscan2
- MUC16 | c.3225A>G p.K1075= | Silent (SNP) | VAF 84/360 reads (23%) | called by mutect2, varscan2
- NBEA | c.57C>T p.L19= | Silent (SNP) | VAF 85/481 reads (18%) | catalogued as rs1167760473; called by mutect2, varscan2
- OR5H14 | c.678G>A p.L226= | Silent (SNP) | VAF 24/228 reads (11%) | catalogued as COSV71194273; called by mutect2, varscan2
- P2RY1 | c.624C>T p.D208= | Silent (SNP) | VAF 84/396 reads (21%) | called by mutect2, varscan2
- PCDH15 | c.2253A>G p.Q751= | Silent (SNP) | VAF 36/312 reads (12%) | catalogued as rs74905541, COSV57257788, COSV57271951; called by mutect2, varscan2
- PCSK2 | c.1737G>A p.P579= | Silent (SNP) | VAF 80/574 reads (14%) | catalogued as rs780477445, COSV52731210; called by mutect2, varscan2
- POM121L2 | c.1584T>G p.T528= | Silent (SNP) | VAF 146/423 reads (35%) | catalogued as COSV66274967; called by mutect2, varscan2
- SOX3 | c.1185C>T p.G395= | Silent (SNP) | VAF 110/222 reads (50%) | called by mutect2, varscan2
- TEX15 | c.492A>G p.V164= (on ENST00000256246; = p.V547= on NM_001350162.2) | Silent (SNP) | VAF 48/228 reads (21%) | called by mutect2, varscan2
- TNFRSF12A | c.378G>A p.A126= | Silent (SNP) | VAF 106/408 reads (26%) | catalogued as rs963655038; called by mutect2, varscan2
- TTN | c.30066A>G p.E10022= (on ENST00000591111; = p.E9095= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/466 reads (22%) | called by mutect2, varscan2
- VAV1 | c.2139C>A p.V713= | Silent (SNP) | VAF 48/264 reads (18%) | called by mutect2, varscan2
- VWDE | c.4722T>C p.T1574= | Silent (SNP) | VAF 78/382 reads (20%) | called by mutect2, varscan2
- ZFHX3 | c.9999G>A p.Q3333= | Silent (SNP) | VAF 164/409 reads (40%) | catalogued as rs1279438043; called by mutect2, varscan2
- SPEF2 | c.4448-3350T>G | Intron (SNP) | VAF 47/362 reads (13%) | called by mutect2, varscan2
- TTN | c.34522+254A>C | Intron (SNP) | VAF 32/144 reads (22%) | called by mutect2, varscan2
- ZNF8 | c.66+57G>C | Intron (SNP) | VAF 241/530 reads (45%) | called by mutect2, varscan2
